Gene-level copy-number profile of tumor specimen TCGA-G8-6909-01A from TCGA case TCGA-G8-6909, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Intrathoracic lymph nodes; Age at diagnosis: 67.5 years (24,661 days).
Specimen TCGA-G8-6909-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-DLBC.7c1555c9-336c-474b-997a-5d6229e3469e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G8-6909-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/692c811b-3041-47a0-8077-11f4f6093507

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 127; copy number 1: 1,784; copy number 2: 50,326; copy number 3: 7,072; copy number 4: 27; copy number 6: 2; copy number 7: 199; copy number 8: 282.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-G8-6909-01A-11D-2209-01): tumor purity 0.52, ploidy 2.14, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 127 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:137,143,820–139,043,302, 34 genes: IL22RA2, IFNGR1, OLIG3, BTF3L4P3, AL356234.2, AL356234.3, AL356234.1, LINC02539, Y_RNA, WAKMAR2, TNFAIP3, AL591468.1, LINC02528, LINC02865, RPSAP42, PERP, ARFGEF3, PBOV1, SMIM28, AL031003.1, MARCKSL1P2, HEBP2, NHSL1, MIR3145, AL391669.1, AL590617.1, AL590617.2, CCDC28A-AS1, CCDC28A, ECT2L, ACKR4P1, AL121834.1, REPS1, ABRACL.
- chr8:58,991,720–59,123,478, 2 genes: AC105150.1, AC090152.1.
- chr14:105,703,995–106,293,808, 91 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 483 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:36,837,698–36,966,536, 1 gene, copy number 8 (within-gene range 2–8): STRN.
- chr2:36,867,398–65,432,637, 471 genes, copy number 7–8 (broad region; genes not listed).
- chr2:65,439,838–65,793,533, 9 genes, copy number 8: AC012370.2, DNAJB12P1, RPS15AP15, RN7SL635P, VTRNA2-2P, AC007389.2, AC007389.3, KRT18P33, AC007741.1.
- chr7:51,773,836–51,864,798, 2 genes, copy number 6: AC006478.1, AC006478.2.

Autosomal genes at a single copy (total copy number 1): 1,657. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
